TCGA case TCGA-DU-6396 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/152eaa99-05f5-4d30-bfb1-494a9a900e49

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 31 years; Vital status: Dead; Days to death: 2,286 days (6.3 years).

Diagnoses (2)
1. Mixed glioma (the primary disease): ICD-O-3 morphology code: 9382/3; ICD-10 code: C71.0; Tissue or organ of origin: Cerebrum; Site of resection or biopsy: Nervous system, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 31.3 years (11,427 days); Year of diagnosis: 1996; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; First symptom longest duration: 0-30 Days; First symptom prior to diagnosis: Motor or Movement Changes; Sites of involvement: Brain, Frontal lobe; Supratentorial localization: White Matter.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Treatment intent type: Adjuvant; Days to treatment start: 25 days; Days to treatment end: 25 days; Treatment dose: 800 cGy; Course number: 1; Number of fractions: 1; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiosensitizing Agent; Therapeutic agents: Broxuridine; Treatment intent type: Adjuvant; Days to treatment start: 28 days; Days to treatment end: 59 days; Number of cycles: 1; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 28 days; Days to treatment end: 59 days; Treatment dose: 5,940 cGy; Course number: 2; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine + Procarbazine + Vincristine; Treatment intent type: Adjuvant; Regimen or line of therapy: PCV; Days to treatment start: 82 days; Days to treatment end: 89 days; Number of cycles: 1; Route of administration: Intravenous / Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Aminocamptothecin; Initial disease status: Progressive Disease; Days to treatment start: 240 days; Days to treatment end: 636 days (1.7 years); Number of cycles: 18; Treatment dose: 1,611 mg/m2; Prescribed dose: 1611; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Initial disease status: Progressive Disease; Days to treatment start: 915 days (2.5 years); Days to treatment end: 1,062 days (2.9 years); Number of cycles: 4; Prescribed dose: 125; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 1,762 days (4.8 years); Days to treatment end: 2,188 days (6.0 years); Number of cycles: 7; Treatment dose: 225 mg; Prescribed dose: 150; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Isotretinoin; Initial disease status: Progressive Disease; Days to treatment start: 1,823 days (5.0 years); Days to treatment end: 1,946 days (5.3 years); Number of cycles: 4; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Initial disease status: Progressive Disease; Days to treatment start: 1,825 days (5.0 years); Days to treatment end: 1,825 days (5.0 years); Treatment dose: 1,800 cGy; Course number: 3; Number of fractions: 1; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Radiation, Intensity-Modulated Radiotherapy; Initial disease status: Progressive Disease; Days to treatment start: 2,066 days (5.7 years); Days to treatment end: 2,097 days (5.7 years); Treatment dose: 5,600 cGy; Course number: 4; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Initial disease status: Progressive Disease; Days to treatment start: 2,127 days (5.8 years); Days to treatment end: 2,250 days (6.2 years); Number of cycles: 4; Treatment dose: 160 mg; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Initial disease status: Progressive Disease; Days to treatment start: 2,198 days (6.0 years); Days to treatment end: 2,216 days (6.1 years); Treatment dose: 3,000 cGy; Course number: 5; Number of fractions: 6; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Initial disease status: Progressive Disease; Days to treatment start: 2,250 days (6.2 years); Days to treatment end: 2,250 days (6.2 years); Number of cycles: 1; Treatment dose: 3,500 mg; Route of administration: Oral.
   Recorded as not given: Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis.
2. Recurrence of diagnosis 1 (Mixed glioma). Age at diagnosis: 31.6 years (11,533 days); Days to diagnosis: 106 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 169 days; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Distant Site.

Follow-up (4 entries)
- Day 19 (prior to adjuvant therapy): Karnofsky performance status: 90.
- Day 106 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 106 days.
- Days to follow up: 2,286 days (6.3 years); Disease response: With Tumor.
- ECOG performance status: 0; Timepoint: Post Adjuvant Therapy.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Headache / Motor / Movement Change / Sensory Changes.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DU-6396-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 1; Shortest dimension: 1.
  Slide TCGA-DU-6396-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-DU-6396-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-DU-6396-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DU-6396-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Oligoastrocytoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; History ionizing radiation to head: No; Tumor status: With tumor; Performance status timing: Pre-Adjuvant Therapy; Tumor site: Supratentorial, Frontal Lobe; History seizures: No; History headaches: Yes; Symp changes mental status: No; Symp changes visual: No; Symp changes sensory: Yes; Symp changes motor movement: Yes; Related symptom first present: Motor/Movement Changes; First symptom longest duration: 0 - 30 Days; Family history brain tumor: No; Idh1 mutation test indicator: No.
- Drug treatment 1: Regimen number: 5; Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Regimen number: 4; Therapy regimen: Progression.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Drug treatment 3: Regimen number: 3; Pharmaceutical therapy drug name: 9 Aminocamptothecin; Therapy regimen: Progression.
- Drug treatment 4: Regimen number: 6; Therapy regimen: Progression.
- Drug treatment 5: Regimen number: 7; Therapy regimen: Progression.
- Drug treatment 6: Regimen number: 1; Pharmaceutical therapy drug name: Bromo deoxyuridine.
- Drug treatment 7: Regimen number: 2.
- Drug treatment 7, Route of administrations: Route of administration: IV; Route of administration: PO.
- Radiation treatment 2: Radiation type other: Stereotactic radiosurgery; Therapy regimen: Progression.
- Radiation treatment 3: Radiation type other: Stereo Radiosurgery.
- Radiation treatment 4: Radiation type other: Intensity Modulated Radio Therapy; Therapy regimen: Progression.
- Radiation treatment 5: Radiation type other: Fractionated stereotactic radio therapy; Therapy regimen: Progression.
- Follow-up form: New tumor event surgery: Yes; Tumor status: With tumor; New tumor event pharmaceutical treatment: Yes; New tumor event radiation treatment: Yes; Performance status timing: Post-Adjuvant Therapy; New tumor event surgery met: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,286 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,286 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 106 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DU-6396-01A-11D-1704-01): tumor purity 0.63, ploidy 3.85, whole-genome doublings 1.
